Somatic mutation profile of tumor specimen 0DW8GU from CCDI case PBCNMN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 10.3 years (3,754 days).
Specimen 0DW8GU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78144dbf-ac9e-4791-8a90-4378ad00048b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW8GJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58ae2462-2b28-43e6-9211-c8f889ab0f0e

The open-access MAF lists 98 somatic variants for this specimen: 58 protein-altering or splice-affecting, 21 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 21, Intron 8, 5'UTR 7, Frame Shift Del 5, 3'UTR 4, Splice Site 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALKBH8 | c.1184C>G p.P395R | Missense Mutation (SNP) | VAF 121/578 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52838110; called by muse, mutect2, varscan2
- ANGPT2 | c.418C>G p.R140G | Missense Mutation (SNP) | VAF 98/1327 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV57334909; called by muse, mutect2
- BAIAP2L2 | c.544C>G p.R182G | Missense Mutation (SNP) | VAF 127/400 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1030186966, COSV100207250; called by muse, mutect2, varscan2
- C2orf16 | c.1026C>G p.H342Q | Missense Mutation (SNP) | VAF 140/675 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.423); catalogued as COSV68645688; called by muse, mutect2, varscan2
- CNTN5 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 153/793 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201856589; called by muse, mutect2, varscan2
- CNTNAP4 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 131/360 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs374909736, COSV56681989, COSV56698811; called by muse, mutect2, varscan2
- KRT16 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 128/424 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.053); catalogued as rs1383463670, COSV56968949; called by muse, mutect2, varscan2
- LRRC18 | c.26A>C p.K9T | Missense Mutation (SNP) | VAF 103/320 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs755944332; called by muse, mutect2, varscan2
- PALD1 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 162/478 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs1270939655, COSV54979194, COSV99698781; called by muse, mutect2, varscan2
- PASK | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.805); catalogued as COSV52150286, COSV99299917; called by muse, mutect2, varscan2
- PCDHA12 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 92/289 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.082); catalogued as rs200698690, COSV56539607; called by muse, mutect2, varscan2
- PFKFB4 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 118/314 reads (38%) | PolyPhen benign (0.003); catalogued as COSV51679829; called by mutect2, varscan2
- PTCHD3 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs147881350; called by muse, mutect2, varscan2
- SHOX2 | c.539C>T p.S180L (on ENST00000441443 / NM_006884.3; = p.S204L on NM_003030.4) | Missense Mutation (SNP) | VAF 98/489 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101273727, COSV67463954, COSV67464313; called by muse, mutect2, varscan2
- SLC9C1 | c.3010G>A p.A1004T | Missense Mutation (SNP) | VAF 155/695 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as rs374547341; called by muse, mutect2, varscan2
- ST8SIA2 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 167/485 reads (34%) | PolyPhen probably damaging (1); catalogued as rs770430761; called by mutect2, varscan2
- SYNGR4 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs778187227, COSV61225267; called by muse, mutect2, varscan2
- TNFRSF11B | c.481A>G p.R161G | Missense Mutation (SNP) | VAF 41/1730 reads (2%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV52074333, COSV99816791; called by muse, mutect2
- TTN | c.55871C>A p.A18624D (on ENST00000591111; = p.A11200D on NM_003319.4) | Missense Mutation (SNP) | VAF 96/418 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV60093551; called by muse, mutect2, varscan2
- VPS13D | c.1399C>A p.P467T | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.275); catalogued as COSV62527713; called by muse, mutect2, varscan2
- AC100868.1 | c.1542G>A p.M514I | Missense Mutation (SNP) | VAF 144/1466 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2
- ACVRL1 | c.758A>C p.H253P | Missense Mutation (SNP) | VAF 126/538 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADD2 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 100/521 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKFY1 | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 91/501 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARIH1 | c.983A>T p.D328V | Missense Mutation (SNP) | VAF 155/471 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- C4BPA | c.1610A>C p.K537T | Missense Mutation (SNP) | VAF 97/288 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- DCHS2 | c.1676T>C p.M559T | Missense Mutation (SNP) | VAF 162/402 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND1C | c.1693G>C p.D565H | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, varscan2
- DENND1C | c.1670T>G p.L557R | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, varscan2
- E2F8 | c.850_853del p.I284* | Frame Shift Del (DEL) | VAF 184/836 reads (22%) | called by mutect2, varscan2
- ERICH1 | c.288C>G p.S96R | Missense Mutation (SNP) | VAF 90/851 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- FBXO22 | c.990del p.Q332Sfs*37 | Frame Shift Del (DEL) | VAF 108/369 reads (29%) | called by mutect2, varscan2
- GATA4 | c.982T>A p.S328T | Missense Mutation (SNP) | VAF 92/1632 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- GLS | c.815+1G>T p.X272_splice | Splice Site (SNP) | VAF 95/388 reads (24%) | called by muse, mutect2, varscan2
- GSAP | c.2276T>C p.I759T | Missense Mutation (SNP) | VAF 21/700 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- HNRNPU | c.1346C>A p.T449K (on ENST00000283179; = p.T511K on NM_004501.3) | Missense Mutation (SNP) | VAF 135/575 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- MYO18A | c.3131T>A p.V1044E | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYO5A | c.3810G>T p.R1270S | Missense Mutation (SNP) | VAF 20/693 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2
- NF1 | c.6590_6591del p.F2197Cfs*44 (on ENST00000358273 / NM_001042492.3; = p.F2176Cfs*44 on NM_000267.3) | Frame Shift Del (DEL) | VAF 126/494 reads (26%) | called by mutect2, varscan2
- NLRP1 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 31/531 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- OMA1 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 137/436 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- OR4A16 | c.209T>G p.I70R | Missense Mutation (SNP) | VAF 108/495 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- OR8K5 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 121/592 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PIK3R4 | c.3139A>G p.T1047A | Missense Mutation (SNP) | VAF 135/637 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POLQ | c.961-2A>G p.X321_splice | Splice Site (SNP) | VAF 22/381 reads (6%) | called by muse, mutect2
- PRR30 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RFPL3 | c.910T>C p.S304P (on ENST00000249007 / NM_001098535.1; = p.S275P on NM_006604.2) | Missense Mutation (SNP) | VAF 23/748 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RNF213 | c.6735G>C p.R2245S | Missense Mutation (SNP) | VAF 158/668 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SEC22B | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 160/483 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SGIP1 | c.879C>A p.S293R | Missense Mutation (SNP) | VAF 164/525 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- SLC25A46 | c.445A>T p.S149C | Missense Mutation (SNP) | VAF 112/376 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, varscan2
- SLC4A4 | c.1570A>C p.T524P (on ENST00000264485 / NM_001098484.3; = p.T480P on NM_003759.4) | Missense Mutation (SNP) | VAF 32/902 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- TRANK1 | c.6023A>C p.K2008T | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- VPS50 | c.1592_1593del p.K531Rfs*2 | Frame Shift Del (DEL) | VAF 164/602 reads (27%) | called by mutect2, varscan2
- VSTM1 | c.487+1G>T p.X163_splice | Splice Site (SNP) | VAF 24/494 reads (5%) | called by muse, mutect2
- YLPM1 | c.3793_3796del p.W1265Mfs*106 | Frame Shift Del (DEL) | VAF 40/182 reads (22%) | called by mutect2, varscan2
- ZMAT4 | c.78A>T p.E26D | Missense Mutation (SNP) | VAF 146/1436 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- ZNF277 | c.599A>T p.N200I | Missense Mutation (SNP) | VAF 100/661 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CACNG5 | c.363A>G p.G121= | Silent (SNP) | VAF 22/774 reads (3%) | called by muse, mutect2
- COL15A1 | c.2064C>T p.G688= | Silent (SNP) | VAF 93/362 reads (26%) | called by muse, mutect2, varscan2
- FBRSL1 | c.2697C>T p.R899= | Silent (SNP) | VAF 76/293 reads (26%) | called by muse, mutect2, varscan2
- HNRNPU | c.1347A>T p.T449= (on ENST00000283179; = p.T511= on NM_004501.3) | Silent (SNP) | VAF 135/574 reads (24%) | called by muse, mutect2, varscan2
- KAT6A | c.5640G>T p.S1880= | Silent (SNP) | VAF 88/602 reads (15%) | called by muse, mutect2, varscan2
- LMLN2 | c.156C>T p.T52= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs949378979; called by muse, mutect2, varscan2
- MCUR1 | c.234G>A p.P78= | Silent (SNP) | VAF 56/94 reads (60%) | called by muse, mutect2, varscan2
- PLCH2 | c.3228G>C p.T1076= | Silent (SNP) | VAF 100/260 reads (38%) | called by muse, mutect2, varscan2
- PLIN4 | c.2628C>G p.V876= (on ENST00000301286; = p.V891= on NM_001367868.2) | Silent (SNP) | VAF 41/422 reads (10%) | catalogued as rs557521224; called by muse, mutect2
- PLIN5 | c.639C>T p.Y213= | Silent (SNP) | VAF 68/164 reads (41%) | catalogued as rs755578583, COSV67850553; called by muse, mutect2, varscan2
- PTK2B | c.2184C>A p.T728= | Silent (SNP) | VAF 147/1350 reads (11%) | called by muse, mutect2, varscan2
- RFPL4A | c.444C>T p.S148= | Silent (SNP) | VAF 101/952 reads (11%) | catalogued as rs769869192; called by muse, mutect2
- RFPL4AL1 | c.444C>T p.S148= | Silent (SNP) | VAF 117/634 reads (18%) | catalogued as rs1413512344; called by muse, varscan2
- SBSN | c.1719G>A p.T573= (on ENST00000452271 / NM_001166034.2; = p.T230= on NM_198538.4) | Silent (SNP) | VAF 57/207 reads (28%) | catalogued as rs377009732; called by muse, mutect2, varscan2
- SH2D3A | c.573G>T p.L191= | Silent (SNP) | VAF 85/241 reads (35%) | called by muse, mutect2, varscan2
- STYX | c.255G>T p.L85= | Silent (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- TM7SF3 | c.1383C>T p.N461= | Silent (SNP) | VAF 184/842 reads (22%) | catalogued as rs773697487, COSV58001867; called by muse, mutect2, varscan2
- TRAPPC6A | c.231G>A p.V77= (on ENST00000585934 / NM_001270891.2; = p.V91= on NM_024108.3) | Silent (SNP) | VAF 83/233 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.64281C>G p.G21427= (on ENST00000591111; = p.G14003= on NM_003319.4) | Silent (SNP) | VAF 162/711 reads (23%) | catalogued as COSV60105735; called by muse, mutect2, varscan2
- UBALD1 | c.162C>T p.Y54= | Silent (SNP) | VAF 84/268 reads (31%) | catalogued as rs773502844; called by muse, mutect2, varscan2
- ZAR1L | c.621C>T p.A207= | Silent (SNP) | VAF 133/526 reads (25%) | catalogued as rs370322886; called by muse, mutect2, varscan2
- AGBL4 | c.-100C>T | 5'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- CLIP1 | c.-98C>A | 5'UTR (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2
- COPS2 | c.715+50T>A | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, varscan2
- CTCFL | c.1059+117T>A | Intron (SNP) | VAF 99/405 reads (24%) | called by muse, mutect2, varscan2
- CYHR1 | c.246+1864T>C | Intron (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- FAR2 | c.723+29T>C | Intron (SNP) | VAF 19/477 reads (4%) | called by muse, mutect2
- LRRFIP1 | c.-65G>T | 5'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2
- MFF | c.38+90_38+91del | Intron (DEL) | VAF 14/75 reads (19%) | called by mutect2, varscan2
- MICAL2 | c.3142+20C>A | Intron (SNP) | VAF 65/221 reads (29%) | catalogued as rs755756578; called by muse, mutect2, varscan2
- MTFP1 | c.-63G>T | 5'UTR (SNP) | VAF 4/29 reads (14%) | called by muse, varscan2
- NDEL1 | c.-51G>T | 5'UTR (SNP) | VAF 47/141 reads (33%) | called by muse, mutect2, varscan2
- PLXNB3 | c.*7G>C | 3'UTR (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- PPFIBP2 | c.1068+72C>G | Intron (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- PREX2 | c.*32G>T | 3'UTR (SNP) | VAF 192/1625 reads (12%) | called by muse, mutect2, varscan2
- PRKDC | c.967-46A>C | Intron (SNP) | VAF 29/263 reads (11%) | called by muse, mutect2, varscan2
- RBM5 | c.-18T>G | 5'UTR (SNP) | VAF 21/646 reads (3%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 17/106 reads (16%) | called by muse, varscan2
- ZC2HC1C | c.*56C>A | 3'UTR (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- ZFYVE19 | c.*74C>A | 3'UTR (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100146276; called by muse, mutect2, varscan2
